MMRF case MMRF_1842 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7f47229a-3446-449e-b8db-9ac102b13f82

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.2 years (20,514 days); ISS stage: I; Days to last known disease status: 1,094 days (3.0 years); Days to last follow up: 1,094 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 103 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 159 days; Days to treatment end: 159 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 159 days; Days to treatment end: 159 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 227 days; Days to treatment end: 689 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 732 days (2.0 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 732 days (2.0 years); Days to treatment end: 884 days (2.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 732 days (2.0 years); Days to treatment end: 897 days (2.5 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 898 days (2.5 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 898 days (2.5 years); Days to treatment end: 1,072 days (2.9 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,094 days (3.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4: M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 301 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 46.4 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 10 g/dL; Glucose 6.55 mmol/L; C-Reactive Protein 0.5 mg/dL.
- Day 64 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Hemoglobin 7.69 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 6.44 mmol/L.
- Day 190 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.18 mg/dL; Hemoglobin 7.44 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 5.67 mmol/L.
- Day 260 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 1.88 g/L; Immunoglobulin M 0.414 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 8 g/dL; Glucose 6.6 mmol/L.
- Day 354 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.65 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.334 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 7.6 g/dL; Glucose 5.72 mmol/L.
- Day 466 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.41 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 8.36 mmol/L.
- Day 548 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.34 mg/dL; Immunoglobulin G 18.8 g/L; Immunoglobulin A 2.72 g/L; Immunoglobulin M 0.246 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.9 g/dL; Glucose 7.65 mmol/L.
- Day 583 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 2.6 g/L; Immunoglobulin M 0.336 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 8.3 g/dL; Glucose 6.93 mmol/L.
- Day 731 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.65 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 3.16 g/L; Immunoglobulin M 0.375 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 8.2 g/dL; Glucose 9.08 mmol/L.
- Day 814 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Immunoglobulin G 18.2 g/L; Immunoglobulin A 1.87 g/L; Immunoglobulin M 0.153 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 7.9 g/dL; Glucose 9.9 mmol/L.
- Day 892 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 117 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.13 mg/dL; Immunoglobulin G 25.1 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.148 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 7.9 g/dL; Glucose 7.1 mmol/L.
- Day 996 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 8.2 g/dL; Glucose 10.7 mmol/L.
- Day 1,094 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 61.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.09 mg/dL; Immunoglobulin G 16.3 g/L; Immunoglobulin A 0.703 g/L; Immunoglobulin M 0.114 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 8.1 g/dL; Glucose 8.58 mmol/L.

Other clinical attributes
- Day -4: Weight: 88 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1842_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1842_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
